Gene-level copy-number profile of tumor specimen TCGA-AA-A00L-01A from TCGA case TCGA-AA-A00L, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.6 years (24,319 days).
Specimen TCGA-AA-A00L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6c163d64-d734-4235-8e00-09786ef15058.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/136d0459-dc35-4f3c-b566-f4dd915360ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 4,924; copy number 2: 47,263; copy number 3: 5,012; copy number 4: 1,082; copy number 5: 1,410; copy number 6: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A00L-01): tumor purity 0.79, ploidy 2.11, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr4:183,987,669–184,474,550, 12 genes (within-gene range 0–1): AC074194.1, AC074194.2, AC107222.1, ENPP6, AC107222.2, AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79.
- chr20:14,933,843–14,935,363, 1 gene: AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,445 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,160,366, 28 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21.
- chr7:70,972–9,985,895, 214 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:10,449,820–19,002,416, 86 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:18,948,898–62,275,678, 775 genes, copy number 5 (broad region; genes not listed).
- chr13:56,885,284–71,867,204, 117 genes, copy number 5 (broad region; genes not listed).
- chr13:72,453,902–73,661,891, 22 genes, copy number 5: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:77,919,689–78,617,328, 1 gene, copy number 5 (within-gene range 4–5): OBI1-AS1.
- chr13:78,275,720–81,691,072, 39 genes, copy number 5: AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr13:82,823,131–82,824,136, 1 gene, copy number 5: GYG1P2.
- chr13:83,298,071–97,187,578, 137 genes, copy number 5 (broad region; genes not listed).
- chr13:104,814,327–106,568,137, 18 genes, copy number 5 (within-gene range 5–6): RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1.
- chr17:46,029,916–46,225,389, 1 gene, copy number 6 (within-gene range 3–6): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 6: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 4,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
